Somatic mutation profile of tumor specimen TCGA-10-0933-01A (aliquot TCGA-10-0933-01A-01W-0420-08) from TCGA case TCGA-10-0933, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 77.8 years (28,433 days).
Specimen TCGA-10-0933-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88ddbfd3-cdb3-451d-95a8-e2eaf89d6def.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-10-0933-11A (Solid Tissue Normal), aliquot TCGA-10-0933-11A-01W-0420-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b7438b2-abd9-4a6d-a033-a42a0ff77a9a

The open-access MAF lists 63 somatic variants for this specimen: 47 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 15, Nonsense Mutation 3, Splice Site 2, Frame Shift Del 2, RNA 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.2359C>T p.R787* | Nonsense Mutation (SNP) | VAF 311/338 reads (92%) | hotspot (GDC flag); catalogued as rs137853293, CM900196, COSV57296164; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.2473C>T p.R825W | Missense Mutation (SNP) | VAF 87/208 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.289); catalogued as rs771542253, COSV60917951; called by muse, mutect2, varscan2
- ATP9A | c.855T>A p.N285K | Missense Mutation (SNP) | VAF 99/485 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV58771465; called by muse, mutect2, varscan2
- CAMTA2 | c.910C>A p.P304T | Missense Mutation (SNP) | VAF 55/61 reads (90%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.991); catalogued as COSV61838058; called by muse, mutect2, varscan2
- CCM2L | c.934G>T p.D312Y | Missense Mutation (SNP) | VAF 62/372 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV52952510; called by muse, mutect2, varscan2
- CD93 | c.1373G>A p.W458* | Nonsense Mutation (SNP) | VAF 21/105 reads (20%) | catalogued as rs766261091, COSV99849550; called by muse, mutect2, varscan2
- CENPF | c.3841A>G p.T1281A | Missense Mutation (SNP) | VAF 99/174 reads (57%) | SIFT tolerated (0.49); PolyPhen benign (0.012); catalogued as rs1223033692, COSV65278740; called by muse, mutect2, varscan2
- CENPQ | c.266A>G p.E89G | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV59922129; called by muse, mutect2, varscan2
- CLTCL1 | c.1391G>A p.G464E | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99595798; called by muse, varscan2
- DISP3 | c.3800C>T p.P1267L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53836684; called by muse, mutect2, varscan2
- DNAH10 | c.6571C>A p.Q2191K (on ENST00000409039; = p.Q2130K on NM_207437.3) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.786); catalogued as COSV101292650; called by muse, mutect2
- DNM1 | c.2171G>A p.R724Q | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV57855769; called by muse, mutect2, varscan2
- DTX1 | c.1792G>A p.A598T | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs759015998, COSV55659494; called by muse, mutect2, varscan2
- FAM47C | c.1801A>G p.T601A | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV63730156; called by muse, varscan2
- FLG | c.11675G>A p.R3892Q | Missense Mutation (SNP) | VAF 46/210 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs372348813, COSV64242241; called by muse, mutect2, varscan2
- HHIP | c.1423+2T>C p.X475_splice | Splice Site (SNP) | VAF 148/239 reads (62%) | catalogued as COSV56843795; called by muse, mutect2, varscan2
- HNRNPF | c.781G>A p.G261R | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.473); catalogued as rs778316977, COSV100563271; called by muse, mutect2
- KLHDC7A | c.709G>A p.G237R | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT tolerated (0.13); PolyPhen benign (0.061); catalogued as COSV68770919; called by muse, mutect2, varscan2
- MAOB | c.820T>A p.F274I | Missense Mutation (SNP) | VAF 261/595 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV65206771; called by muse, mutect2, varscan2
- MLLT3 | c.656A>G p.K219R | Missense Mutation (SNP) | VAF 262/956 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.011); catalogued as COSV63501988; called by muse, mutect2, varscan2
- MROH6 | c.1049T>C p.M350T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as rs760169466, COSV99435546; called by muse, mutect2
- MXRA5 | c.2272G>A p.V758I | Missense Mutation (SNP) | VAF 55/121 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV54249199; called by muse, mutect2, varscan2
- OVCH1 | c.3251G>T p.W1084L | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.013); catalogued as COSV58967781; called by muse, mutect2, varscan2
- PCDH7 | c.1681G>A p.D561N | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62342660; called by muse, varscan2
- PCDHA13 | c.1217C>T p.S406L | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99169657; called by muse, mutect2
- PEAK1 | c.3593G>A p.S1198N | Missense Mutation (SNP) | VAF 95/181 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56942623; called by muse, mutect2, varscan2
- PGBD2 | c.1187G>C p.G396A | Missense Mutation (SNP) | VAF 36/218 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61401071; called by muse, mutect2, varscan2
- PPP1R26 | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0.024); catalogued as rs150815603; called by muse, mutect2, varscan2
- PROSER3 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 61/449 reads (14%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.775); catalogued as rs755976528, COSV56554153; called by muse, mutect2, varscan2
- PSMB4 | c.266G>T p.R89L | Missense Mutation (SNP) | VAF 170/846 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV51853158; called by muse, mutect2, varscan2
- PWWP3A | c.23T>G p.V8G (on ENST00000627377; = p.V7G on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100262253, COSV60902586; called by muse, mutect2, varscan2
- RHOA | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 105/236 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); catalogued as COSV101371152, COSV69043583, COSV99069255; called by muse, mutect2, varscan2
- SAE1 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 92/325 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs538083905, COSV54298820; called by muse, mutect2, varscan2
- STRIP1 | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 108/278 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.023); catalogued as COSV63931206; called by muse, mutect2, varscan2
- TET3 | c.611C>A p.S204* | Nonsense Mutation (SNP) | VAF 4/60 reads (7%) | catalogued as COSV99996589, COSV99996723; called by muse, mutect2
- UNC119B | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.216); catalogued as COSV60865754; called by mutect2, varscan2
- VPS16 | c.2506G>A p.A836T | Missense Mutation (SNP) | VAF 268/434 reads (62%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV66799036; called by muse, mutect2, varscan2
- ZFAND2A | c.330del p.M110Ifs*? | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | catalogued as COSV57181093; called by mutect2, pindel, varscan2
- ZFC3H1 | c.1597A>G p.M533V | Missense Mutation (SNP) | VAF 61/136 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV66432650; called by muse, mutect2, varscan2
- ZNF133 | c.1418G>T p.R473L (on ENST00000316358 / NM_001352454.2; = p.R472L on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100315454; called by muse, varscan2
- ZNF512 | c.196G>T p.D66Y | Missense Mutation (SNP) | VAF 147/216 reads (68%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.121); catalogued as COSV62678126; called by muse, mutect2, varscan2
- APOL6 | c.596A>C p.N199T | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); called by mutect2, varscan2
- BPTF | c.6084G>A p.E2028= | Splice Region (SNP) | VAF 11/402 reads (3%) | called by muse, mutect2
- MYH8 | c.373T>C p.C125R | Missense Mutation (SNP) | VAF 71/260 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); called by muse, varscan2
- NPAP1 | c.317dup p.R107Efs*26 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by pindel, varscan2
- NR4A2 | c.1159-6_1163del p.X387_splice | Splice Site (DEL) | VAF 1285/1514 reads (85%) | called by mutect2, pindel*
- TP53 | c.394_398del p.K132Vfs*15 | Frame Shift Del (DEL) | VAF 131/164 reads (80%) | called by mutect2, pindel, varscan2
- BNC2 | c.1143A>G p.T381= | Silent (SNP) | VAF 84/256 reads (33%) | catalogued as COSV66156482; called by muse, mutect2, varscan2
- COL6A3 | c.3021A>G p.P1007= | Silent (SNP) | VAF 285/891 reads (32%) | catalogued as COSV55107595; called by muse, mutect2, varscan2
- DYRK1B | c.156C>T p.L52= | Silent (SNP) | VAF 64/281 reads (23%) | catalogued as rs763244310, COSV55683941; called by muse, mutect2, varscan2
- EGFL8 | c.255G>A p.V85= | Silent (SNP) | VAF 20/224 reads (9%) | called by muse, mutect2
- FRMPD4 | c.2505G>A p.E835= | Silent (SNP) | VAF 14/244 reads (6%) | catalogued as COSV101044005; called by muse, mutect2
- IRS1 | c.2202C>T p.N734= | Silent (SNP) | VAF 29/140 reads (21%) | catalogued as rs537151982, COSV100524910, COSV59336762; called by mutect2, varscan2
- KCNC1 | c.1308G>A p.V436= | Silent (SNP) | VAF 12/158 reads (8%) | catalogued as COSV99789706; called by muse, mutect2
- LCN12 | c.159C>T p.F53= | Silent (SNP) | VAF 14/122 reads (11%) | catalogued as COSV100861341; called by muse, mutect2, varscan2
- MAX | c.369C>T p.Y123= | Silent (SNP) | VAF 126/427 reads (30%) | catalogued as COSV99408639; called by muse, mutect2, varscan2
- NLRP8 | c.699C>T p.Y233= | Silent (SNP) | VAF 70/258 reads (27%) | catalogued as rs377108884; called by muse, mutect2, varscan2
- PTPRG | c.117C>T p.H39= | Silent (SNP) | VAF 81/178 reads (46%) | catalogued as rs753540838, COSV55661375; called by muse, mutect2, varscan2
- SPNS1 | c.297C>T p.L99= | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as rs1426957851, COSV57955478; called by muse, mutect2, varscan2
- TRIO | c.4923C>T p.A1641= | Silent (SNP) | VAF 74/328 reads (23%) | catalogued as COSV100710923; called by muse, mutect2, varscan2
- UBC | c.372G>A p.K124= | Silent (SNP) | VAF 30/510 reads (6%) | catalogued as rs577374084, COSV60060778; called by muse, mutect2
- UGT8 | c.483C>T p.G161= | Silent (SNP) | VAF 50/105 reads (48%) | catalogued as rs368584974, COSV60420654; called by muse, mutect2, varscan2
- MIR412 | n.79G>A | RNA (SNP) | VAF 26/103 reads (25%) | catalogued as rs368964407; called by muse, mutect2
